Gene-level copy-number profile of tumor specimen TCGA-DY-A0XA-01A from TCGA case TCGA-DY-A0XA, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectosigmoid junction; AJCC pathologic stage: Stage IIA; Age at diagnosis: 57.8 years (21,115 days).
Specimen TCGA-DY-A0XA-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-READ.93a8cac0-b390-48b8-966e-a7828591b1cd.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DY-A0XA-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/250a06c8-e0a2-4e36-b280-d563ad9adc49

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 2: 5,400; copy number 3: 9,131; copy number 4: 35,122; copy number 5: 5,903; copy number 7: 1,655; copy number 8: 1,302; copy number 9: 993; copy number 10: 60; copy number 12: 11; copy number 13: 26; copy number 14: 8; copy number 15: 29; copy number 16: 46; copy number 18: 21; copy number 21: 26; copy number 23: 27; copy number 28: 10; copy number 37: 26; copy number 41: 24.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DY-A0XA-01A-11D-A151-01): tumor purity 0.7, ploidy 4.06, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,307 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:30,831,544–32,855,666, 19 genes, copy number 9–14 (within-gene range 2–14): TEX15, AC090281.1, AC008066.1, PURG, WRN, SUMO2P16, AC009563.1, KCTD9P6, AC068672.2, AC068672.3, AC068672.1, AC090816.1, RNA5SP261, NRG1, AC068931.1, NRG1-IT1, RNA5SP262, RNA5SP263, NRG1-IT3.
- chr12:66,767–4,615,302, 110 genes, copy number 13–37 (within-gene range 4–37) (broad region; genes not listed).
- chr12:8,602,170–9,208,395, 26 genes, copy number 21 (within-gene range 4–21): AICDA, AC092184.2, HADHAP2, MFAP5, AC092490.2, AC092490.3, RIMKLB, RPSAP51, A2ML1-AS1, AC092490.1, A2ML1-AS2, A2ML1, AC006581.2, PHC1, M6PR, KLRG1, AC006581.1, HNRNPA1P34, VDAC2P2, LINC00612, A2M-AS1, A2M, KRT17P8, BTG1P1, PZP, TPT1P12.
- chr12:10,158,301–10,777,446, 24 genes, copy number 41: OLR1, TMEM52B, GABARAPL1, GABARAPL1-AS1, KLRD1, LINC02617, LINC02598, KLRK1-AS1, KLRK1, KLRC4-KLRK1, KLRC4, AC068775.1, KLRC3, KLRC2, KLRC1, EIF2S3B, SLC25A39P2, LINC02446, KLRA1P, MAGOHB, STYK1, YBX3, LINC02366, HSPE1P12.
- chr13:23,730,189–29,595,688, 129 genes, copy number 9–16 (broad region; genes not listed).
- chr13:70,564,267–76,014,501, 60 genes, copy number 10: AL445264.1, MTCL1P1, LINC00348, RABEPKP1, DACH1, H3P36, RPL21P109, RPL35AP31, RPS10P21, AL139003.1, RPL18AP17, AL139003.2, AL356754.2, AL356754.1, RPL21P110, RNU6-80P, MZT1, BORA, DIS3, PIBF1, RNU6-79P, PSMD10P3, KLF5, FABP5P1, RNU6-66P, RNU4-10P, RNY1P8, AL162376.1, MARK2P12, LINC00393, LINC00392, KLF12, AL138713.1, AL159972.1, LINC00402, AL353660.1, RNY1P5, RPL21P108, AL355390.1, LINC00381, AL355390.2, LINC00347, RIOK3P1, RNU6-38P, SSR1P2, CTAGE11P, LINC01078, TBC1D4, AL139230.1, COMMD6, UCHL3, AL137782.1, LMO7-AS1, LMO7, AL137244.1, FAM204CP, LMO7DN, LMO7DN-IT1, LINC00561, LINC01034.
- chr13:77,919,689–78,617,328, 1 gene, copy number 15 (within-gene range 7–15): OBI1-AS1.
- chr13:78,275,720–81,691,072, 39 genes, copy number 12–15: AL138957.1, SRGNP1, RNY3P3, RPL31P54, ELOCP23, AL445209.1, POU4F1, OBI1, RPL21P111, LINC00331, HSPD1P8, CCT5P2, NIPA2P5, BCAS2P3, RBM26, RNA5SP33, RBM26-AS1, NDFIP2-AS1, NDFIP2, LINC01068, AL136442.1, LINC01038, LINC00382, AL158064.1, LINC01080, AL137781.1, SPRY2, RNU6-61P, HNRNPA1P31, PWWP2AP1, AL590807.1, ARF4P4, LINC00377, DPPA3P3, LINC00564, AL353633.1, RNU6-77P, HIGD1AP2, PTMAP5.
- chr20:30,214,765–64,313,132, 899 genes, copy number 9 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
